Somatic mutation profile of tumor specimen TCGA-63-A5MT-01A (aliquot TCGA-63-A5MT-01A-21D-A26M-08) from TCGA case TCGA-63-A5MT, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5728578-4502-4fe6-a664-27b35e0d30a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MT-10A (Blood Derived Normal), aliquot TCGA-63-A5MT-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8614587b-c03f-4230-be0e-f21f607070ea

The open-access MAF lists 241 somatic variants for this specimen: 177 protein-altering or splice-affecting, 55 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 55, Nonsense Mutation 10, Frame Shift Del 5, Splice Site 5, RNA 5, Intron 2, Frame Shift Ins 1, In Frame Ins 1, Nonstop Mutation 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>T p.X187_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | hotspot (GDC flag); catalogued as CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; called by muse, mutect2, varscan2
- ABCB1 | c.1593G>C p.L531F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99711841; called by muse, mutect2, varscan2
- AC100868.1 | c.1357A>C p.T453P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV99224992; called by muse, mutect2, varscan2
- ACACB | c.4153G>T p.V1385F | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100622152; called by muse, mutect2, varscan2
- ADAM21 | c.1978C>A p.P660T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99960335; called by muse, mutect2, varscan2
- ADAMTS20 | c.5056G>T p.G1686C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101238693, COSV99081219; called by muse, mutect2, varscan2
- ADARB1 | c.1996C>T p.R666C (on ENST00000360697 / NM_001346687.2; = p.R626C on NM_001112.4) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100653559; called by muse, mutect2, varscan2
- ADGRB3 | c.521G>T p.W174L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100999521; called by muse, mutect2, varscan2
- ADGRB3 | c.522G>T p.W174C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65411199; called by muse, mutect2, varscan2
- ALMS1 | c.11351C>G p.T3784S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV100040821; called by muse, mutect2, varscan2
- ANKS4B | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100289679; called by muse, mutect2, varscan2
- ANO6 | c.2644C>A p.H882N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100261984; called by muse, mutect2, varscan2
- APOB | c.4141G>C p.D1381H | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99262941; called by muse, mutect2, varscan2
- APOBEC3G | c.282G>C p.W94C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101349031, COSV68470025; called by muse, mutect2, varscan2
- ARMC2 | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as rs1468192863, COSV99410722; called by muse, mutect2, varscan2
- ARMC4 | c.779T>G p.L260R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99518039; called by muse, mutect2, varscan2
- ATP13A5 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV100664602; called by muse, mutect2, varscan2
- ATP8A2 | c.1397+1G>A p.X466_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99679357; called by muse, mutect2, varscan2
- AVL9 | c.1720G>C p.D574H | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100594464; called by muse, mutect2, varscan2
- BTN1A1 | c.808A>G p.R270G | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV99764095; called by muse, mutect2, varscan2
- CALHM4 | c.659A>G p.Y220C (on ENST00000368596 / NM_001366078.1; = p.Y34C on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100888827; called by muse, mutect2, varscan2
- CCDC93 | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV100098204; called by muse, mutect2, varscan2
- CCN2 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.08); catalogued as COSV100915266; called by muse, mutect2, varscan2
- CCSER1 | c.1132G>C p.G378R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.061); catalogued as COSV100387088; called by muse, mutect2, varscan2
- CDC42EP1 | c.238A>T p.S80C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99312307; called by muse, mutect2, varscan2
- CDH2 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99295179; called by muse, mutect2, varscan2
- CEP152 | c.3910C>T p.R1304C (on ENST00000380950 / NM_001194998.2; = p.R1248C on NM_014985.4) | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376099036, COSV100358385; called by muse, mutect2, varscan2
- CEP170 | c.4434G>T p.Q1478H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100316231; called by muse, mutect2, varscan2
- CEP70 | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.286); catalogued as COSV99388715; called by muse, mutect2, varscan2
- CFAP44 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs755015228, COSV99868700; called by muse, mutect2, varscan2
- CHAT | c.1315G>T p.V439L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV60336131; called by muse, mutect2, varscan2
- CLVS2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV99251956; called by muse, mutect2, varscan2
- COG6 | c.919T>C p.Y307H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141212095, COSV100742536; called by muse, mutect2, varscan2
- CPNE3 | c.1451G>C p.R484T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99547026; called by muse, mutect2, varscan2
- CREBBP | c.5470G>A p.A1824T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52113813, COSV52118969; called by muse, mutect2, varscan2
- CTCF | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as COSV50525552, COSV99864080; called by muse, mutect2, varscan2
- DEPDC5 | c.1607C>G p.P536R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99834055; called by muse, mutect2, varscan2
- DMRT1 | c.921C>G p.F307L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV101206607; called by muse, mutect2, varscan2
- DNAH17 | c.4567A>T p.I1523F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV101101090; called by muse, mutect2, varscan2
- DNAH5 | c.851G>C p.R284P | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.886); catalogued as rs769557353, COSV99443519; called by muse, mutect2, varscan2
- DNAJA2 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100398765; called by muse, mutect2
- DPPA4 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV100169142; called by muse, mutect2, varscan2
- DRC1 | c.2036C>G p.A679G | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV99716189; called by muse, mutect2, varscan2
- EPHA4 | c.1603+2T>A p.X535_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99915193; called by muse, mutect2, varscan2
- EPHA5 | c.2237-1G>C p.X746_splice | Splice Site (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99895169; called by muse, mutect2
- EXTL2 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV100921070; called by muse, mutect2, varscan2
- FAM135B | c.1817C>A p.S606Y | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as COSV52719715, COSV99417311; called by muse, mutect2, varscan2
- FOXL2NB | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100374279, COSV57730934; called by muse, mutect2, varscan2
- GBP6 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV100969433; called by muse, mutect2, varscan2
- GJD2 | c.594C>G p.F198L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.777); catalogued as COSV99290520; called by muse, mutect2, varscan2
- GLG1 | c.3058G>C p.E1020Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV99215131; called by muse, mutect2, varscan2
- GLYATL1 | c.907T>C p.*303Qext*14 (on ENST00000317391 / NM_001354699.1; = p.*334Qext*14 on NM_080661.4) | Nonstop Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as rs746019229, COSV100265075; called by muse, mutect2, varscan2
- GOPC | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99270621; called by muse, mutect2
- GORAB | c.402G>C p.E134D | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as COSV100883749; called by muse, mutect2, varscan2
- GRIP1 | c.2664G>C p.E888D (on ENST00000359742 / NM_001379345.1; = p.E836D on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV54015409, COSV99667564, COSV99668325; called by muse, mutect2, varscan2
- GRIPAP1 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100904143; called by muse, mutect2, varscan2
- HAVCR1 | c.572C>A p.P191Q | Missense Mutation (SNP) | VAF 72/347 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.354); catalogued as COSV100207807; called by muse, mutect2, varscan2
- HCN1 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs771934361, COSV57513144, COSV99079147; called by muse, mutect2, varscan2
- IGSF1 | c.3713C>T p.S1238L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100811754, COSV100812395; called by muse, mutect2, varscan2
- INPP5F | c.3109C>G p.Q1037E | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.006); catalogued as rs1564860063, COSV100739934; called by muse, mutect2, varscan2
- ITPKB | c.1864G>T p.D622Y | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99683519; called by muse, mutect2, varscan2
- KMO | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086890; called by muse, mutect2, varscan2
- KRT3 | c.827T>G p.L276R | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100526847, COSV58816918; called by muse, mutect2, varscan2
- LAMA2 | c.1745A>G p.Y582C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759283737, COSV101369842; called by muse, mutect2, varscan2
- LAMA2 | c.2002C>A p.P668T | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as COSV101369843; called by muse, mutect2
- LAMA2 | c.5318G>A p.R1773Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs573287715, COSV70344193; called by muse, mutect2, varscan2
- LAMA4 | c.2366C>A p.T789N (on ENST00000230538 / NM_001105206.3; = p.T782N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.599); catalogued as COSV100037387; called by muse, mutect2, varscan2
- LAMA4 | c.2275C>A p.L759I (on ENST00000230538 / NM_001105206.3; = p.L752I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100037389, COSV57902171; called by muse, mutect2, varscan2
- LAMA4 | c.1469A>G p.E490G (on ENST00000230538 / NM_001105206.3; = p.E483G on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.471); catalogued as COSV100037391; called by muse, mutect2
- LCT | c.5196C>G p.I1732M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as COSV99928294; called by muse, mutect2, varscan2
- LRP1B | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs773459049, COSV67208275; called by muse, mutect2, varscan2
- LRP5 | c.2767G>A p.G923S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.052); catalogued as rs771724060, COSV53724108, COSV99591166; called by muse, mutect2, varscan2
- LRRC43 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100336465, COSV60290651; called by muse, mutect2
- LRRTM1 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.474); catalogued as COSV54440978, COSV99701541; called by muse, mutect2, varscan2
- MAGEB3 | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100854572; called by muse, mutect2, varscan2
- MAN1A2 | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100740749; called by muse, mutect2, varscan2
- MAPK8 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100827338; called by muse, mutect2, varscan2
- MARCHF11 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs779149046, COSV100197208; called by muse, mutect2
- MICAL2 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 24/808 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.271); catalogued as COSV99816526; called by muse, mutect2
- MRGPRX2 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 7/99 reads (7%) | catalogued as COSV100316589; called by muse, mutect2
- MRPL55 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99686701; called by muse, mutect2, varscan2
- MUC17 | c.2219C>G p.S740* | Nonsense Mutation (SNP) | VAF 66/389 reads (17%) | catalogued as COSV100071128; called by muse, mutect2, varscan2
- MYO7B | c.5882T>C p.V1961A | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); catalogued as COSV100263982; called by muse, mutect2
- NBAS | c.4417C>T p.H1473Y | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV55724280; called by muse, mutect2, varscan2
- NEB | c.12357G>T p.L4119F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99413660; called by muse, mutect2, varscan2
- NEO1 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs550492839, COSV56067319, COSV56080736; called by muse, mutect2, varscan2
- NLRC5 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52655076; called by muse, mutect2, varscan2
- NLRP2 | c.2971C>G p.Q991E | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV99671732; called by muse, mutect2, varscan2
- NOD1 | c.1366G>C p.G456R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV99767707; called by muse, mutect2, varscan2
- OCA2 | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 37/183 reads (20%) | catalogued as CX942057, COSV100666778, COSV62337529; called by muse, mutect2, varscan2
- OR2AK2 | c.605G>C p.S202T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.429); catalogued as COSV100822944; called by muse, mutect2, varscan2
- OR4A47 | c.673A>G p.N225D | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV101487043; called by muse, mutect2, varscan2
- OR4C13 | c.94A>T p.I32F | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as rs1250304846, COSV101634130; called by muse, mutect2, varscan2
- OR5D14 | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV100161996; called by muse, mutect2, varscan2
- OR9G4 | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100264953; called by muse, mutect2, varscan2
- P4HA1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as COSV99696465; called by muse, mutect2, varscan2
- PARP4 | c.3932C>T p.S1311F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV101131224; called by muse, mutect2, varscan2
- PCDHA1 | c.1532A>G p.H511R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100974233; called by muse, mutect2, varscan2
- PCDHGB2 | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99528469; called by muse, mutect2, varscan2
- PIK3C2G | c.3085C>T p.P1029S (on ENST00000676171; = p.P988S on NM_004570.5) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.332); catalogued as COSV56800721, COSV99848712; called by muse, mutect2
- PLA2R1 | c.3469C>T p.H1157Y | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99321912; called by muse, mutect2, varscan2
- PLCB3 | c.3258G>T p.M1086I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99657033; called by muse, mutect2, varscan2
- PLCD4 | c.1517G>T p.R506L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as COSV101346830; called by muse, mutect2, varscan2
- PMS1 | c.2450G>A p.G817D | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781206054, COSV100575393; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1592G>C p.C531S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as COSV99460621; called by muse, mutect2, varscan2
- PRDM1 | c.1054C>A p.P352T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100958476; called by muse, mutect2, varscan2
- PRKCI | c.1079C>A p.A360E | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99855577; called by muse, mutect2, varscan2
- PRODH2 | c.1426+2T>A p.X476_splice (on ENST00000301175; = p.X400_splice on NM_021232.2 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 14/146 reads (10%) | catalogued as COSV99995100; called by muse, mutect2
- PROM2 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs145616061; called by muse, mutect2, varscan2
- PRUNE2 | c.5137G>C p.E1713Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV100944171, COSV65044490; called by muse, mutect2, varscan2
- PSG4 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV54939214, COSV99736001; called by muse, mutect2, varscan2
- PSMA1 | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 22/656 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV101123606; called by muse, mutect2
- PSMC6 | c.163G>A p.E55K (on ENST00000612399; = p.E41K on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.341); catalogued as rs1228178955, COSV101471171, COSV101471172; called by muse, mutect2, varscan2
- PUM2 | c.2095A>T p.R699W | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); catalogued as COSV100162999; called by muse, mutect2, varscan2
- REV3L | c.2479C>A p.P827T | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100724720; called by muse, mutect2, varscan2
- RFX5 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV100923798; called by muse, mutect2, varscan2
- RPS6KA1 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100837856; called by muse, mutect2, varscan2
- RTL3 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as COSV100329473; called by muse, mutect2, varscan2
- RUFY1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100105613; called by muse, mutect2, varscan2
- RUSF1 | c.1245G>C p.E415D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100392934; called by muse, mutect2, varscan2
- RYR2 | c.3385G>T p.G1129C | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63696507; called by muse, mutect2, varscan2
- RYR2 | c.3386G>T p.G1129V | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100767177, COSV100770288; called by muse, mutect2, varscan2
- RYR2 | c.5494G>T p.G1832C | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63679447; called by muse, mutect2, varscan2
- RYR3 | c.14154C>G p.H4718Q (on ENST00000389232; = p.H4719Q on NM_001036.6) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211803; called by muse, mutect2, varscan2
- SAMD9 | c.3256C>T p.Q1086* | Nonsense Mutation (SNP) | VAF 28/154 reads (18%) | catalogued as rs775859770, COSV101180105; called by muse, mutect2, varscan2
- SH3RF2 | c.1045A>T p.S349C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100767548; called by muse, mutect2, varscan2
- SI | c.4057G>T p.V1353F | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100013409; called by muse, mutect2
- SI | c.1422C>G p.Y474* | Nonsense Mutation (SNP) | VAF 40/256 reads (16%) | catalogued as COSV100013410; called by muse, mutect2
- SI | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as COSV100013414; called by muse, mutect2, varscan2
- SIGLEC5 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV99706947; called by muse, mutect2, varscan2
- SLC25A47 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100836430; called by muse, mutect2, varscan2
- SLC5A2 | c.505G>C p.A169P | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555495710, COSV100392933, COSV57892238; called by muse, mutect2, varscan2
- SLCO1B1 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57015641, COSV99917803; called by muse, mutect2, varscan2
- SLITRK1 | c.1343A>T p.N448I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV100999731; called by muse, mutect2, varscan2
- SOX13 | c.945G>C p.M315I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99689823; called by muse, mutect2
- STS | c.1324A>G p.N442D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV99480840; called by muse, mutect2, varscan2
- SUFU | c.1327A>T p.M443L | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100883264; called by muse, mutect2, varscan2
- TAF7 | c.898A>T p.K300* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100514879; called by muse, mutect2, varscan2
- TCHH | c.2760G>C p.K920N | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV100914851; called by muse, mutect2, varscan2
- TENM1 | c.2258C>T p.T753I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100948776; called by muse, mutect2, varscan2
- TENT5A | c.751A>G p.M251V | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100198704; called by muse, mutect2, varscan2
- THBS2 | c.2048G>T p.G683V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100827483; called by mutect2, varscan2
- TIAM1 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99731920; called by muse, mutect2
- TKTL2 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99760985; called by muse, mutect2, varscan2
- TMEM14C | c.241T>C p.Y81H | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as COSV99994409; called by muse, mutect2, varscan2
- TNRC6B | c.4901C>T p.S1634L (on ENST00000454349 / NM_001162501.2; = p.S1524L on NM_015088.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1367455484, COSV57293567; called by muse, mutect2
- TNXB | c.9772G>C p.E3258Q (on ENST00000647633; = p.E3011Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV100925675; called by muse, mutect2, varscan2
- TRIM11 | c.15C>G p.D5E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99487946; called by muse, mutect2, varscan2
- TRPM1 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 105/661 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99855152; called by muse, mutect2, varscan2
- TTN | c.87392A>G p.K29131R (on ENST00000591111; = p.K21707R on NM_003319.4) | Missense Mutation (SNP) | VAF 17/101 reads (17%) | PolyPhen probably damaging (0.994); catalogued as COSV100589425; called by muse, mutect2, varscan2
- TTN | c.86933C>A p.T28978K (on ENST00000591111; = p.T21554K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | PolyPhen possibly damaging (0.813); catalogued as COSV100589427; called by muse, mutect2
- TTN | c.62405G>C p.R20802P (on ENST00000591111; = p.R13378P on NM_003319.4) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | PolyPhen benign (0.007); catalogued as COSV100589429; called by muse, mutect2, varscan2
- TUT7 | c.2908C>T p.R970* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | catalogued as COSV99462248; called by muse, mutect2, varscan2
- UEVLD | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV55579187; called by muse, mutect2
- UMPS | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228653; called by muse, mutect2, varscan2
- USP34 | c.6676G>C p.E2226Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101276516; called by muse, mutect2, varscan2
- XKR3 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); catalogued as COSV100509095; called by muse, mutect2
- ZBTB2 | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100287456; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1715C>T p.T572I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58745266; called by muse, mutect2, varscan2
- ZNF133 | c.416G>A p.W139* (on ENST00000316358 / NM_001352454.2; = p.W138* on NM_003434.7 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/150 reads (18%) | catalogued as COSV100315239; called by muse, mutect2, varscan2
- ZNF638 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as rs192912662, COSV52489441; called by muse, mutect2, varscan2
- ZNF836 | c.1889G>C p.R630T | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.311); catalogued as COSV100440501, COSV59080964; called by muse, mutect2, varscan2
- ZNF846 | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs1332750999, COSV101194245; called by muse, mutect2, varscan2
- ZNF91 | c.2761C>G p.Q921E | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.597); catalogued as COSV100321889; called by muse, mutect2, varscan2
- ZSCAN18 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99558971; called by muse, mutect2, varscan2
- ZSCAN2 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as rs1419626754, COSV100491435, COSV100491507; called by muse, mutect2, varscan2
- ZSWIM8 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV101289739; called by muse, mutect2, varscan2
- GADD45A | c.410_415dup p.D137_P138dup | In Frame Ins (INS) | VAF 14/87 reads (16%) | called by mutect2, varscan2
- IGHV3-11 | c.55T>A p.C19S | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- MXRA5 | c.3761del p.G1254Dfs*31 | Frame Shift Del (DEL) | VAF 44/99 reads (44%) | called by mutect2, pindel, varscan2
- NCDN | c.749dup p.T251Dfs*6 | Frame Shift Ins (INS) | VAF 24/148 reads (16%) | called by mutect2, pindel, varscan2
- NUP85 | c.531_580del p.D178Qfs*17 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel
- PLEKHG3 | c.2794_2795del p.L932Ifs*2 (on ENST00000394691; = p.L988Ifs*2 on NM_001308147.2) | Frame Shift Del (DEL) | VAF 17/126 reads (13%) | called by pindel, varscan2
- PPP1R13B | c.696_698del p.L233del | In Frame Del (DEL) | VAF 15/109 reads (14%) | called by mutect2, pindel, varscan2
- RABGAP1L | c.1541del p.G514Efs*4 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, pindel, varscan2
- SOX9 | c.1121del p.P374Rfs*9 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- TRAV16 | c.146G>C p.S49T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ADGRL4 | c.339A>G p.A113= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV100875489; called by muse, mutect2, varscan2
- AL645922.1 | c.1116C>G p.P372= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV100190503, COSV100191100; called by muse, mutect2, varscan2
- ARHGAP20 | c.2580C>T p.L860= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs1382347104, COSV52815458; called by muse, mutect2, varscan2
- ATM | c.4842A>G p.L1614= | Silent (SNP) | VAF 60/137 reads (44%) | catalogued as rs1057520429, COSV99586727; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACHD1 | c.2172G>C p.L724= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV99261177; called by muse, mutect2, varscan2
- CEP57 | c.486A>C p.T162= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100334539; called by muse, mutect2, varscan2
- CHAT | c.1314G>T p.V438= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100339527; called by muse, mutect2, varscan2
- COG4 | c.51G>A p.V17= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100091122; called by muse, mutect2
- COPB1 | c.1689G>A p.K563= | Silent (SNP) | VAF 544/653 reads (83%) | catalogued as COSV99999149; called by muse, mutect2, varscan2
- CPN1 | c.600G>A p.V200= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100962514; called by muse, mutect2, varscan2
- DNAJB12 | c.150C>G p.L50= (on ENST00000338820; = p.L16= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1479461080, COSV100123604; called by muse, mutect2, varscan2
- FAM43B | c.231G>T p.L77= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100261430; called by muse, varscan2
- FAT3 | c.2814C>A p.P938= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as COSV53100834; called by muse, mutect2, varscan2
- FETUB | c.771T>C p.F257= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs192905245, COSV54006427; called by muse, mutect2, varscan2
- GABBR2 | c.873G>A p.E291= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV99408878; called by muse, mutect2, varscan2
- GSK3B | c.573T>G p.P191= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99953959; called by muse, mutect2, varscan2
- H2AC12 | c.303C>A p.V101= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV100804550, COSV63617150; called by muse, mutect2, varscan2
- HDAC2 | c.1014T>C p.F338= | Silent (SNP) | VAF 36/218 reads (17%) | catalogued as COSV100892523; called by muse, mutect2, varscan2
- HRC | c.1857G>A p.G619= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99417408; called by muse, mutect2, varscan2
- IGHV7-81 | c.306C>T p.I102= | Silent (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- ITPRID2 | c.3591G>A p.G1197= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs769638770, COSV100237742, COSV57470659; called by muse, mutect2, varscan2
- KCNMA1 | c.2328G>T p.R776= (on ENST00000286628 / NM_001161352.2; = p.R718= on NM_002247.4) | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV54291561, COSV99694244; called by muse, mutect2, varscan2
- LIAS | c.198A>G p.L66= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as rs750722814, COSV99787492; called by muse, mutect2, varscan2
- LRP2 | c.9915C>T p.R3305= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV99785909; called by muse, mutect2, varscan2
- MAT2B | c.217T>C p.L73= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV99796498; called by muse, mutect2, varscan2
- MED13 | c.3378C>T p.F1126= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as rs1458531629; called by muse, mutect2, varscan2
- MS4A8 | c.600C>T p.C200= | Silent (SNP) | VAF 46/231 reads (20%) | catalogued as rs200663288, COSV100282335; called by muse, mutect2, varscan2
- MUC17 | c.6468T>C p.Y2156= | Silent (SNP) | VAF 70/331 reads (21%) | catalogued as COSV60280916; called by muse, mutect2
- NAALADL2 | c.1200T>C p.N400= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs761595467, COSV101379825; called by muse, varscan2
- NLE1 | c.780C>T p.L260= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV62604259; called by muse, mutect2, varscan2
- NOL4 | c.1389C>T p.L463= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs770918277, COSV99304559; called by muse, mutect2, varscan2
- OPTN | c.1200T>C p.H400= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV99537149, COSV99537474; called by muse, mutect2, varscan2
- OR4Q3 | c.405C>A p.I135= | Silent (SNP) | VAF 12/233 reads (5%) | catalogued as COSV100056633; called by muse, mutect2
- OTOL1 | c.1029G>T p.S343= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1464684146, COSV100019691, COSV100020258; called by muse, mutect2, varscan2
- OXER1 | c.171C>T p.L57= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99685150; called by muse, mutect2, varscan2
- PABPC3 | c.246A>G p.V82= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV99878867; called by muse, mutect2, varscan2
- PGAM1 | c.45A>C p.A15= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs564150081, COSV100602385; called by muse, mutect2, varscan2
- PNMT | c.225C>G p.L75= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99510444; called by muse, mutect2, varscan2
- POLE3 | c.285G>A p.E95= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99928107; called by muse, mutect2, varscan2
- PPRC1 | c.1896C>T p.I632= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99531230; called by muse, mutect2, varscan2
- RADIL | c.306G>T p.L102= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV101271200; called by muse, mutect2, varscan2
- RHOT2 | c.1644A>G p.L548= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs747790625, COSV99558539; called by muse, mutect2, varscan2
- RIMS2 | c.3120G>A p.R1040= (on ENST00000666250 / NM_001348490.2; = p.R848= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV99153926; called by muse, mutect2, varscan2
- RPS6KA1 | c.423G>T p.L141= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100837854; called by muse, mutect2, varscan2
- SAYSD1 | c.429G>A p.E143= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV100010016, COSV100010192; called by muse, mutect2
- SETD2 | c.3369A>G p.K1123= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV100337735; called by muse, mutect2, varscan2
- SIM1 | c.2013G>A p.L671= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs201911731, COSV99491752; called by muse, mutect2, varscan2
- SOX13 | c.1326C>T p.I442= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV65827715; called by muse, mutect2, varscan2
- TGFBR1 | c.927G>A p.T309= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs201323409, COSV100895239; ClinVar: benign; called by muse, mutect2, varscan2
- TUBA1C | c.771C>T p.T257= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99988603; called by mutect2, varscan2
- UNC13C | c.1770A>G p.K590= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99510001; called by muse, mutect2, varscan2
- USH2A | c.8586G>A p.Q2862= | Silent (SNP) | VAF 35/199 reads (18%) | called by muse, mutect2, varscan2
- WNK1 | c.3951A>G p.E1317= (on ENST00000315939 / NM_018979.4; = p.E1070= on NM_014823.3) | Silent (SNP) | VAF 18/195 reads (9%) | catalogued as COSV100265882; called by muse, mutect2
- ZEB2 | c.303G>A p.E101= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100354691; called by muse, mutect2, varscan2
- ZNF835 | c.270G>A p.P90= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV73379322, COSV73379564; called by muse, mutect2, varscan2
- CD300LD | chr17:74592746 C>A | 5'Flank (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | n.7622C>T | RNA (SNP) | VAF 4/50 reads (8%) | catalogued as COSV61777634; called by muse, mutect2
- HERC2P3 | n.854G>T | RNA (SNP) | VAF 20/207 reads (10%) | catalogued as rs1370208354; called by muse, mutect2
- LINC00922 | n.796G>T | RNA (SNP) | VAF 30/150 reads (20%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-173G>A | Intron (SNP) | VAF 41/71 reads (58%) | catalogued as rs775066383, COSV100024652; called by muse, mutect2, varscan2
- MIR297 | n.58C>G | RNA (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- NDUFA13 | c.-13G>T | 5'UTR (SNP) | VAF 13/67 reads (19%) | catalogued as rs569723556, COSV99388849, COSV99389157; called by muse, mutect2, varscan2
- SSPOP | n.12053G>A | RNA (SNP) | VAF 8/24 reads (33%) | catalogued as rs759086312, COSV100946902; called by muse, mutect2, varscan2
- TPD52 | c.507-1515A>G | Intron (SNP) | VAF 24/33 reads (73%) | catalogued as rs1230148426, COSV100990669; called by muse, mutect2, varscan2
